Somatic mutation profile of tumor specimen TCGA-B2-5635-01A (aliquot TCGA-B2-5635-01A-01D-A270-10) from TCGA case TCGA-B2-5635, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.4 years (27,183 days).
Specimen TCGA-B2-5635-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec83fe4d-da08-455f-b6a0-32dfae433e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5635-10A (Blood Derived Normal), aliquot TCGA-B2-5635-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d0b71d6-3a1b-40c0-8e49-4572c5b32627

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 13, Frame Shift Del 7, Splice Site 2, Intron 1, Translation Start Site 1, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.431del p.G144Dfs*15 | Frame Shift Del (DEL) | VAF 54/124 reads (44%) | catalogued as rs869025651, CM058403, CM982008, COSV56544477, COSV56545017; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACOX3 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62710847; called by muse, mutect2, varscan2
- AKR1B15 | c.809A>G p.K270R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV71151044, COSV71152438; called by muse, mutect2, varscan2
- AMOTL1 | c.1970A>G p.N657S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58565068; called by muse, mutect2, varscan2
- C1orf198 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.367); catalogued as COSV100793515; called by muse, mutect2, varscan2
- CADPS | c.3724G>C p.D1242H | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51867480; called by muse, mutect2, varscan2
- CD300C | c.548G>C p.R183P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV58169559; called by muse, mutect2, varscan2
- CHRDL2 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs1272782634, COSV55221695; called by muse, mutect2, varscan2
- DAPK1 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs370466694; called by muse, mutect2, varscan2
- DNAH5 | c.12436T>G p.S4146A | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as COSV54204617, COSV54231804; called by muse, mutect2, varscan2
- DOP1A | c.7054G>C p.V2352L | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV52706914; called by muse, mutect2, varscan2
- DVL3 | c.1988G>C p.G663A | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.142); catalogued as COSV99491018; called by muse, mutect2, varscan2
- EIF2A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs1304044022, COSV53525429; called by muse, mutect2, varscan2
- EPB41L5 | c.329-1del p.X110_splice | Splice Site (DEL) | VAF 45/235 reads (19%) | catalogued as COSV99758863; called by mutect2, pindel, varscan2
- F12 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as rs773373088, COSV99499971; called by muse, mutect2, varscan2
- FRMPD4 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as rs149409320, COSV66211401; ClinVar: benign; called by muse, mutect2, varscan2
- GCNT2 | c.929T>C p.V310A (on ENST00000379597 / NM_001374747.1; = p.V308A on NM_001491.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.028); catalogued as COSV53941111; called by muse, varscan2
- GLI3 | c.2432-1G>T p.X811_splice | Splice Site (SNP) | VAF 17/62 reads (27%) | catalogued as COSV101230108; called by muse, mutect2, varscan2
- IFT140 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); catalogued as COSV68485941; called by muse, mutect2, varscan2
- KAT6B | c.5771C>G p.S1924C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV54742321; called by muse, mutect2, varscan2
- KCNJ4 | c.1257C>G p.F419L | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs755886046, COSV100341556, COSV57856658; called by muse, mutect2, varscan2
- KCNV2 | c.1385A>G p.D462G | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66055548; called by muse, mutect2, varscan2
- KIAA1586 | c.226T>A p.L76M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV66056158; called by muse, mutect2, varscan2
- KTI12 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs775602415, COSV65405591; called by muse, mutect2, varscan2
- MBTD1 | c.1090T>A p.F364I | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV64502808; called by muse, mutect2, varscan2
- MCCC1 | c.1151C>G p.A384G | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55606382; called by muse, mutect2, varscan2
- MED13 | c.2015T>C p.V672A | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV67261969; called by muse, mutect2, varscan2
- MUC16 | c.21268C>G p.L7090V | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763621010, COSV67445588; called by muse, mutect2, varscan2
- NBAS | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV55712855, COSV55713784; called by muse, mutect2, varscan2
- NDUFC1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1291900266, COSV55499317; called by muse, mutect2, varscan2
- NEBL | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV65799488; called by muse, mutect2, varscan2
- PKP4 | c.2858C>A p.A953E | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61577877; called by muse, mutect2, varscan2
- PLEKHA2 | c.33_34del p.C11Wfs*9 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | catalogued as rs940962664; called by pindel, varscan2
- POLI | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99471281; called by muse, mutect2, varscan2
- PPP2R2B | c.349C>A p.L117M (on ENST00000394409; = p.L183M on NM_181674.2) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60753665; called by muse, mutect2, varscan2
- PXDN | c.3205G>A p.A1069T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53227201, COSV53241593; called by muse, mutect2, varscan2
- RDX | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); catalogued as rs150863373; called by muse, mutect2, varscan2
- RTN1 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774918300, COSV50718848, COSV99955912; called by muse, mutect2, varscan2
- TM6SF1 | c.976A>G p.R326G | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51943091, COSV51944282; called by muse, mutect2, varscan2
- TSNAXIP1 | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV54648201; called by muse, mutect2, varscan2
- TSNAXIP1 | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV54648209; called by muse, mutect2, varscan2
- USF3 | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV57069902; called by muse, mutect2, varscan2
- ZNF433 | c.1820T>C p.M607T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.159); catalogued as COSV61398410; called by muse, mutect2, varscan2
- AHNAK2 | c.14814_14831del p.E4938_A4944delinsD | In Frame Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- APC | c.3909_3915del p.I1304Kfs*2 | Frame Shift Del (DEL) | VAF 34/202 reads (17%) | called by mutect2, pindel, varscan2
- COPA | c.2176_2183del p.R726Hfs*13 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- ESCO2 | c.417del p.K139Nfs*6 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- HCN1 | c.695T>G p.V232G | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- KDM5C | c.711_751del p.Q237Hfs*12 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel
- LRP2 | c.13647del p.N4549Kfs*8 | Frame Shift Del (DEL) | VAF 48/148 reads (32%) | called by mutect2, pindel*, varscan2
- PLA2G4F | c.1692dup p.A565Cfs*6 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- TSC22D2 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2
- ABL2 | c.114G>A p.A38= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV100859755; called by muse, mutect2, varscan2
- CBFA2T3 | c.1551C>T p.H517= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs1169750562, COSV51923312; called by muse, mutect2, varscan2
- CHD5 | c.567T>G p.G189= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV52407880; called by muse, mutect2, varscan2
- DSG1 | c.3066C>T p.H1022= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV57133270; called by muse, mutect2, varscan2
- HYOU1 | c.2692C>T p.L898= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1465515962, COSV68215151; called by muse, mutect2, varscan2
- IGF1R | c.66G>A p.A22= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV51270402; called by muse, mutect2, varscan2
- OGG1 | c.180G>C p.A60= | Silent (SNP) | VAF 58/115 reads (50%) | catalogued as rs368830432, COSV57351350; called by muse, mutect2, varscan2
- PDIA6 | c.1281C>T p.L427= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV55349161, COSV99694377; called by muse, mutect2, varscan2
- SIMC1 | c.1053G>A p.R351= (on ENST00000443967 / NM_001308196.1; = p.R370= on NM_001308195.2) | Silent (SNP) | VAF 58/342 reads (17%) | catalogued as COSV57900197; called by muse, varscan2
- SLC5A3 | c.309G>C p.R103= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV62967904; called by muse, mutect2, varscan2
- SLIT2 | c.1998T>C p.F666= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV56560594; called by muse, mutect2, varscan2
- TEKT2 | c.1116G>T p.R372= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV99255650; called by muse, mutect2, varscan2
- TOPBP1 | c.717A>G p.T239= | Silent (SNP) | VAF 44/181 reads (24%) | catalogued as COSV99605950; called by muse, mutect2, varscan2
- ATP6V1G2 | chr6:31548402 C>T | 5'Flank (SNP) | VAF 13/45 reads (29%) | catalogued as rs1280045382, COSV100385504; called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117743 del C | 3'Flank (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- OBSCN | c.18662-2158del | Intron (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
